Gene-level copy-number profile of tumor specimen TCGA-22-4609-01A from TCGA case TCGA-22-4609, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.7 years (29,844 days).
Specimen TCGA-22-4609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a244d0e5-0d22-4bd5-8876-3113ed711996.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4609-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5356f667-2aac-4b4c-b77d-058559cf11d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 16,220; copy number 2: 36,962; copy number 3: 5,499; copy number 4: 72; copy number 5: 121; copy number 6: 710; copy number 7: 140; copy number 8: 11; copy number 11: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4609-01A-21D-2121-01): tumor purity 0.42, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,053 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).
- chr9:32,293,558–37,047,237, 203 genes, copy number 5–11 (broad region; genes not listed).
- chr9:38,147,428–43,045,120, 140 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
